Surgical pathology report (de-identified scan), TCGA case TCGA-55-7911, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7911-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

PROCEDURE DATE: [REDACTED] RECEIVED DATE: [REDACTED] REPORT DATE: [REDACTED]

COPY TO:

Pre-Op Diagnosis
Lung mass
Post-Op Diagnosis
Same as above
Clinical History
Nothing indicated
Gross Description:
Four parts

Container labeled [REDACTED] lymph node" is 0.9 x 0.8 x 0.7 cm irregular portion of focally shaggy gray tan to brown tissue with an indurated focally chalky gray tan to yellow friable nodule measuring 0.4 cm on sectioning. Sectioned specimen is entirely submitted in a single cassette.

Container labeled [REDACTED] lymph node" is 1.5 x 1.0 x 0.4 cm elongated and irregular shaggy gray brown to black fleshy tissue fragments entirely submitted in a single cassette.

Container labeled [REDACTED] right lung middle lobe" is 69 gram portion of recognizable pulmonary parenchyma with appears grossly consistent with right middle lobe of lung. This is partially sectioned and has a closed staple line as the margin of resection. The specimen is received after tissue harvest for genomic study. The specimen on reconstruction is 10.0 x 9.6 x up to 3.3 cm. The margin of resection includes a stapled bronchus. The pleura is wrinkled mottled tan brown. Noted near the staple line margin at a point 3.4 cm from the bronchial margin there is a subpleural well defined lobulated 1.7 x 1.7 x 1.6 cm tan gray fibrotic lesion with a firm slightly gritty tan gray fibrotic cut surface. This grossly appears to focally extend to within 0.3 cm of the stapled parenchymal margin but does not appear to be transected

[REDACTED]

[page 2 of 3]
at this margin. The lesion grossly extends to within 0.1 cm of the pleura but does not grossly extend into it. A grossly recognizable bronchial connection is not identified however several small bronchi appear to extend toward the region of the periphery of the lesion. The staple line is removed. The parenchyma at the remaining active stapled margin is removed and has been inked. The specimen is sectioned to reveal the remaining parenchyma is slightly congested rubbery spongy and pink red without additional nodularity or gross lesions. Also received in the same container are three tissue cassettes each labeled [REDACTED]. Representative sections are submitted labeled as follows: A - shaved bronchial margin; B-F - remaining lesion and surrounding tissue; G - random uninvolved parenchyma.

Container labeled [REDACTED] lymph node" are 3.0 x 2.1 x up to 1.0 cm of soft shaggy gray tan to brown fleshy tissue fragments entirely submitted in two cassettes.

[REDACTED]
Microscopic Description:
Reviewed are slides labeled [REDACTED]

Final Diagnosis

Lymph node, level 7:

One lymph node with prominent dense calcification.
No histologic evidence of metastatic carcinoma identified in sections examined.

Lymph node, level 10, biopsy:

Benign lymph node, multiple fragments, no histologic evidence of metastatic carcinoma identified in sections examined.

Lung, right middle lobe, lobectomy:

Specimen integrity: Received intact.

Histologic type: Adenocarcinoma.

Grade: Moderately differentiated (II).

Tumor site: Right middle lobe.

Tumor focality: Unifocal.

Tumor size: 1.7 x 1.7 x 1.6 cm.

Visceral pleural invasion: Not identified.

Lymphovascular space invasion: No unequivocal lymphovascular space invasion identified in sections examined.

Tumor extension: Tumor confined to pulmonary parenchyma.

Treatment effect: Unknown.

Surgical margin status:

Tumor distance from bronchial margin: 3.4 cm.

Tumor distance from parenchymal margin: 0.3 cm

Tumor distance from pleural surface: 1 mm

Lymph node status: See parts 1, 2, and 4

Other: Organizing pneumonia. PAS 9

Stage pT1aN0

Lymph node, level 8, excision:

Multiple fragments of benign lymph node, no histologic evidence of metastatic carcinoma identified in sections examined. PAS 9 [REDACTED]

CPT: 88305 x2, 88307

Comments

At the request of the undersigned pathologist, these slides have been additionally reviewed by [REDACTED] who concurs with the diagnosis.

[REDACTED]

[page 3 of 3]
This report has been finalized at the [redacted]

<Sign Out Dr. Signature>

[redacted]

Page 1 of 1

Source: NCI Genomic Data Commons file 8a0ff29a-6aa8-49ab-98fb-26be66394449 (TCGA-55-7911.0C8EA3A9-23B7-4C43-8972-3660048B8537.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).